Somatic mutation profile of tumor specimen TCGA-AB-2832-03B (aliquot TCGA-AB-2832-03B-01W-0728-08) from TCGA case TCGA-AB-2832, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute monocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.0 years (21,915 days).
Specimen TCGA-AB-2832-03B: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 399aa9f7-b48d-439f-8a68-945a50cbdfbf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2832-11B (Solid Tissue Normal), aliquot TCGA-AB-2832-11B-01W-0729-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f70ab353-70b8-456c-92bb-4dd72228500e

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.6532G>T p.D2178Y | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CD1310752, COSV61373733; called by muse, mutect2
- BNC1 | c.2116G>A p.V706M | Missense Mutation (SNP) | VAF 39/325 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs145885730; called by muse, mutect2, varscan2
- SREBF2 | c.1660G>A p.V554M | Missense Mutation (SNP) | VAF 106/284 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV63332043; called by mutect2, varscan2
- VASH1 | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1427826999, COSV51337761; called by muse, mutect2, varscan2
